National Lung Screening Trial (NLST) participant 210195 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 60 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 7): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 50 mA, display field of view 37 cm, reconstruction filter GE Bone.
- T1 (day 476): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, display field of view 36 cm, reconstruction filter GE Bone / GE Standard.
- T2 (day 749): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 100 mA, display field of view 36 cm, reconstruction filter GE Bone / GE Standard.

Abnormalities recorded by the reading radiologist on the CT screens (12 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Emphysema.
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T0 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 4: Other potentially significant abnormality above the diaphragm.
- T1 abnormality 1: Emphysema.
- T1 abnormality 2: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 3: Benign lung nodule(s) (benign calcification).
- T2 abnormality 1: Emphysema.
- T2 abnormality 2: Benign lung nodule(s) (benign calcification).
- T2 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 4: Significant cardiovascular abnormality.
- T2 abnormality 5: Significant cardiovascular abnormality.

Lung cancer (2 primary lung cancer records; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T5; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,957, study year T5. Site: main bronchus (ICD-O-3 C34.0), determined from cytology. Primary tumour location: left hilum. Histology: small cell carcinoma, NOS (ICD-O-3 8041/3). AJCC 6th edition staging: stage IIIB (best stage, from clinical TNM); clinical T4 N1 M0 (stage IIIB); pathologic TX. AJCC 7th edition staging: stage IIIA; clinical T4 N1 M0; pathologic TX NX MX. Summary stage: regional. VALCSG stage (the small-cell staging system; ACRIN recorded it for all its lung cancers): extensive.
2. Subsequent primary lung cancer, diagnosed day 1,957, study year T5. Site: middle lobe of lung (ICD-O-3 C34.2), determined from cytology. Histology: squamous cell carcinoma, NOS (ICD-O-3 8070/3). Grade: poorly differentiated (G3). AJCC 6th edition staging: occult carcinoma (TX N0 M0), the best stage, from a mixture of clinical and pathologic TNM components; clinical N0 M0; pathologic TX. AJCC 7th edition staging: occult carcinoma (TX N0 M0); clinical TX N0 M0; pathologic TX NX MX. Summary stage: localized.

Follow-up
Last known free of lung cancer: day 1,957 (for ACRIN participants with lung cancer this field holds the diagnosis date).
